Gene-level copy-number profile of tumor specimen TCGA-06-0210-01B from TCGA case TCGA-06-0210, project TCGA-GBM (Glioblastoma Multiforme). Sex at birth: female; Vital status: Dead; Primary diagnosis: Glioblastoma; Tissue or organ of origin: Brain, NOS; Age at diagnosis: 72.8 years (26,600 days).
Specimen TCGA-06-0210-01B: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-GBM.60342871-d60e-4bfa-9f1c-0615095b3462.gene_level_copy_number.v36.tsv, workflow ASCAT2 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-06-0210-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 349 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/640ada78-2fe8-46ba-aab3-1338cfb09545

Most common (modal) total copy number across autosomal genes: 4 — above the diploid value of 2, consistent with a largely gained or genome-doubled tumor.
Genes by total copy number (all chromosomes): copy number 0: 588; copy number 1: 56; copy number 2: 4,690; copy number 3: 72; copy number 4: 51,528; copy number 5: 183; copy number 6: 3,021; copy number 7: 42; copy number 8: 9; copy number 10: 13; copy number 11: 5; copy number 13: 13; copy number 17: 2; copy number 21: 2; copy number 24: 1; copy number 26: 1; copy number 46: 48.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-06-0210-01B-01D-0236-01): tumor purity 0.45, ploidy 1.96, whole-genome doublings 0.

Homozygous deletions (total copy number 0; autosomes only): 67 genes in 4 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:152,600,662–152,614,098, 2 genes: LCE3C, LCE3B.
- chr2:23,357,516–23,360,376, 1 gene (within-gene range 0–4): AC012506.2.
- chr4:68,509,441–68,616,137, 4 genes: UGT2B29P, UGT2B17, AC147055.2, AC147055.4.
- chr9:20,999,509–23,438,700, 60 genes (within-gene range 0–2): HACD4, IFNNP1, IFNB1, IFNWP4, AL390882.1, IFNW1, Y_RNA, IFNA21, IFNWP15, IFNA4, IFNWP9, IFNA7, IFNA10, IFNWP18, IFNA16, IFNA17, IFNWP5, IFNA14, IFNA22P, IFNA5, IFNA20P, KLHL9, IFNA6, IFNA13, IFNA2, AL353732.1, IFNA11P, IFNA12P, IFNA8, AL353732.2, IFNWP2, IFNA1, MIR31HG, IFNWP19, IFNE, MIR31, SNORD39, H3P30, KHSRPP1, RN7SL151P, MTAP, AL359922.1, TUBB8P1, AL359922.2, AL359922.3, ERVFRD-3, CDKN2A-DT, CDKN2A, CDKN2B-AS1, AL449423.1, CDKN2B, UBA52P6, AL354709.1, AL354709.2, AL157937.1, DMRTA1, LINC01239, AL391117.1, CLIC4P1, AC017067.1.

Amplified relative to the modal value (total copy number ≥ 9, i.e. more than twice the modal value of 4; autosomes only): 85 genes in 9 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:203,318,996–204,829,274, 48 genes, copy number 46: RNU6-487P, FMOD, AL359837.1, LARP7P1, PRELP, OPTC, ATP2B4, NSA2P1, SNORA77, LAX1, ZC3H11A, ZBED6, AC114402.2, AC114402.1, RPL35AP5, SNRPE, KRT8P29, HSPE1P6, CBX1P3, AC096645.1, LINC00303, AL592146.2, SOX13, AL592146.1, ETNK2, ERLNC1, REN, AL592114.2, KISS1, GOLT1A, PLEKHA6, AL592114.3, AL592114.1, LINC00628, AL606489.1, AL606489.2, PPP1R15B, PIK3C2B, MDM4, AL512306.1, RNA5SP74, AL512306.3, LRRN2, AL512306.2, AL161793.1, RNA5SP75, AL161793.2, AC096675.1.
- chr2:4,945,277–4,945,383, 1 gene, copy number 26: RNU6-649P.
- chr2:5,810,641–5,812,670, 1 gene, copy number 24: LINC01810.
- chr2:7,045,329–7,077,916, 1 gene, copy number 21 (within-gene range 4–21): AC068481.1.
- chr4:53,377,839–54,740,715, 23 genes, copy number 10–13 (within-gene range 4–13): AC058822.1, LNX1, LNX1-AS1, AC095040.1, LNX1-AS2, AC124017.1, AC105384.1, AC105384.2, RPL21P44, AC110792.3, CHIC2, AC110792.2, AC110792.4, AC110792.1, MORF4L2P1, GSX2, RPL22P13, PDGFRA, LINC02283, AC098587.1, AC098868.1, LINC02260, KIT.
- chr13:103,043,998–103,066,417, 1 gene, copy number 21: SLC10A2.
- chr13:108,207,439–109,208,005, 8 genes, copy number 10 (within-gene range 6–10): LIG4, ABHD13, TNFSF13B, AL157762.1, RNA5SP39, AL138694.1, HCFC2P1, MYO16.
- chr13:112,052,078–112,052,138, 1 gene, copy number 17: AL138691.1.
- chr13:112,067,149–112,071,706, 1 gene, copy number 17: SOX1.

Autosomal genes at a single copy (total copy number 1): 56. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
